MMRF case MMRF_1775 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6e23a4a7-0f96-47c1-afb6-27699e7afd79

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.0 years (19,740 days); ISS stage: I; Days to last known disease status: 1,083 days (3.0 years); Days to last follow up: 1,083 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 168 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 231 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 268 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 54.6 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 11.8 g/dL; Glucose 6.11 mmol/L; C-Reactive Protein 0.182 mg/dL.
- Day 91 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 183 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 8.64 mmol/L.
- Day 267 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 2.89 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 0.357 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 5.6 g/dL; Glucose 9.35 mmol/L.
- Day 358 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 446 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 4.1 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 544 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 2.84 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 635 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 3.04 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 719 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 3.32 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 810 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 3.95 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 7.43 mmol/L.
- Day 915 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 3.74 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.78 mmol/L.
- Day 999 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 4.19 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.83 mmol/L.
- Day 1,083 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 4.09 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day 1: Weight: 85 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1775_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1775_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
